TARGET case TARGET-30-PAMYPK — Neuroblastoma (TARGET-NBL)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neuroepitheliomatous Neoplasms; Primary site: Retroperitoneum and peritoneum. Index date: not stated by GDC for this case (day counts are relative to an unstated reference).
https://portal.gdc.cancer.gov/cases/8177582f-56c9-51b2-ba27-81d9d828acc1

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Vital status: Dead.

Diagnoses (1)
1. Neuroblastoma, NOS: ICD-O-3 morphology code: 9500/3; Tissue or organ of origin: Retroperitoneum; Age at diagnosis: 3.8 years (1,374 days); Year of diagnosis: 2004; Days to last follow up: 597 days (1.6 years); INSS stage: Stage 4.

Biospecimens (1 sample)
- Sample TARGET-30-PAMYPK-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.
